Somatic mutation profile of tumor specimen TARGET-20-PARUCB-09A (aliquot TARGET-20-PARUCB-09A-01D) from TARGET case TARGET-20-PARUCB, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.3 years (4,121 days).
Specimen TARGET-20-PARUCB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55d3296b-1a5f-4c21-b684-76efea4dfd41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARUCB-14A (Bone Marrow Normal), aliquot TARGET-20-PARUCB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c86c5cca-fa12-4ce5-bf8f-cae8f1b4d026

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Nonsense Mutation 1, Intron 1, Silent 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD1 | c.5431C>T p.R1811* | Nonsense Mutation (SNP) | VAF 58/283 reads (20%) | catalogued as rs587784148, CD119747, CM031303, COSV61771006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEBPA | c.934_936dup p.Q312dup | In Frame Ins (INS) | VAF 26/60 reads (43%) | catalogued as COSV57198430; called by mutect2, varscan2
- PCDHA5 | c.1948G>A p.V650M | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs140011920; called by muse, mutect2
- SLC27A1 | c.980T>C p.I327T | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); catalogued as rs1343982264; called by muse, varscan2
- HNRNPA1 | c.39G>T p.L13= | Silent (SNP) | VAF 78/167 reads (47%) | called by muse, mutect2, varscan2
- SAMD8 | c.943+27C>T | Intron (SNP) | VAF 24/548 reads (4%) | catalogued as rs148645450; called by muse, mutect2
